Surgical pathology report (de-identified scan), TCGA case TCGA-CK-6748, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Harvard, specimen TCGA-CK-6748-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

Accession Number: [REDACTED]
Type: Surgical Pathology
Specimen Type: Liver partial resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

Report Status: Final

CASE: [REDACTED]
PATIENT: [REDACTED]

Resident: [REDACTED]
Pathologist: [REDACTED]

PATHOLOGIC DIAGNOSIS:

- A. SPECIMEN DESIGNATED "LEFT LOBE LIVER WEDGE (104g)" (including FSA):
METASTATIC ADENOCARCINOMA, 5.0 cm, involving liver parenchyma.
Parenchymal resection margin is negative for tumor.
Tumor is 1.0 cm from the parenchymal resection margin.
Hepatic steatosis, mild.
- B. SPECIMEN DESIGNATED "SIGMOID COLON":
ADENOCARCINOMA with mucinous differentiation, high grade, poorly differentiated (5.0 cm in greatest dimension).
Tumor is located in sigmoid colon, forms a fungating mass, is ulcerative, and has an infiltrating border.
Tumor invades through muscularis propria into serosa.
Resection margins are negative for tumor.
Invasive tumor is 5.0 cm from the 4.9 cm stapled resection margin, 7.0 cm from the 3.6 cm stapled resection margin, 2.6 cm from the mesenteric resection margin, and <0.1 cm from the serosal surface.
Lymphovascular invasion is not identified.
Extramural venous invasion is not identified.
Perineural invasion is not identified.
Peritumoral lymphoid response (including Crohn's-like infiltrate) is not present.
Residual adenoma is absent.
Tattoo.
Regional lymph nodes (positive:total): 2:17.
AJCC Classification (6th edition): pT3c N1 M1.
- C. SPECIMEN DESIGNATED "PROXIMAL DONUT":
Portion of colon, negative for tumor.
- D. SPECIMEN DESIGNATED "DISTAL DONUT":
Portion of colon, negative for tumor.

CLINICAL DATA:

History: Colon cancer.
Operation: Laparoscopy, wedge resection L lower lobe of liver and low anterior resection.
Operative Findings: Not provided.
Clinical Diagnosis: Colon Ca. ...

TISSUE SUBMITTED:

- A/1) left lobe liver wedge (FS and Tissue Bank).
B/2) sigmoid colon - Tissue Bank.
C/3) proximal donut.
D/4) distal donut.

O.R. CONSULTATION:

SPECIMEN LABELED "#1 - LEFT LOBE LIVER WEDGE" (FSA):
Metastatic adenocarcinoma.
Surgical resection margin, negative for tumor.

[page 2 of 3]
Pathology Report

The senior physician certifies that he/she personally conducted a gross and/or microscopic examination of the described specimen(s) and rendered or confirmed the rapid diagnos(es) related thereto.

GROSS DESCRIPTION:

The specimen is received fresh, in four parts, each labeled with the patient's name and unit number.

Part A, "left lobe liver wedge", consists of a 100.4-g liver wedge resection (9.0 x 7.2 x 4.2 cm) with a cauterized parenchymal resection margin (9.0 x 4.2 cm, inked blue). On cut sectioning, there is a white/tan focally (approximately 10%) necrotic tumor (5.0 x 4.5 x 3.0 cm) that grossly abuts the liver capsule (inked black) and is located 1.0 cm to the parenchymal resection margin. A representative section of the parenchymal resection margin is submitted as FSA. A representative section of tumor and normal liver is submitted for tissue banking. Representative sections are submitted for histological examination.

Micro A1: FSA remnant, 1 frag, [REDACTED]

Micro A2: Tumor, quick fix, 2 frags, [REDACTED]

Micro A3: Tumor and capsule and tumor and uninvolved liver parenchyma, 2 frags, RSS.

Micro A4: Uninvolved liver, 1 frag, [REDACTED]

Part B, "sigmoid colon", consists of an unoriented segment of colon (16.8 x 2.9 cm in diameter) with two stapled resection margins (4.9 cm and 3.6 cm, both inked black). The specimen is open to reveal a centrally ulcerated mass (5.0 x 4.0 x 1.2 cm) with raised borders that is 5.0 cm to the 4.9 cm stapled resection margin, 7.0 cm from the 3.6 cm stapled resection margin, and 2.6 cm to the mesenteric resection margin (16.8 x 2.3 cm, inked orange). There are two tan/black tattoos (#1 5.0 x 2.5 cm and #2 4.0 x 3.5 cm). Tattoo #1 is located 2.6 cm to the 4.9 cm stapled resection margin and 1.2 cm from the ulcerated mass. Tattoo #2 is located 4.1 cm to the 3.6 cm stapled resection margin and 1.2 cm from the centrally ulcerated mass. Tattoos #1 and #2 are located 7.2 cm from each other and are on opposite sides of the ulcerated mass. Underlying the tattoo #1 is a submucosal firm nodule (0.8 x 0.8 cm) that is located 0.8 cm from the 4.9 cm stapled resection margin and 4.0 cm to the ulcerated mass. Underlying tattoo #2 is a submucosal nodule (1.0 x 0.8 cm) located 6.1 cm to the 3.6 cm stapled resection margin and 2.5 cm from the ulcerated mass. There is an area of serosal puckering immediately deep to the centrally ulcerated mass (1.5 x 0.5 cm) that is located 4.0 cm from the mesenteric resection margin, 7.5 cm from the 4.9 cm stapled resection margin, and 7.0 cm from the 3.6 cm stapled resection margin. Gross photos are taken and representative sections are submitted for histological examination.

Micro B1: 4.9 cm stapled resection margin to include 0.8 cm submucosal nodule, perpendicular, 1 frag, [REDACTED]

Micro B1: 3.6 cm stapled resection margin, perpendicular, 1 frag, [REDACTED]

Micro B3: Remainder of 0.8 cm submucosal nodule, 1 frag, [REDACTED]

Micro B4: 1.0 cm submucosal nodule, 2 frags, [REDACTED]

Micro B5: Mesenteric resection margin, perpendicular, 1 frag, [REDACTED]

Micro B6: Tumor and serosa, deepest extent of invasion, perpendicular, 1 frag, [REDACTED]

Micro B7: Tumor and adjacent uninvolved mucosa closest to 3.6 cm stapled resection margin, 1 frag, [REDACTED]

Micro B8: Tumor and mucosa closest to 4.9 cm stapled resection margin, 1 frag, [REDACTED]

Micro B9: Tumor, 2 frags, [REDACTED]

Micro B10: ? matted lymph nodes (1.8 x 1.5 x 0.8 cm), bisected, 1 frag, [REDACTED]

Micro B11: 5 lymph node candidates, 5 frags, [REDACTED]

Micro B12: 5 lymph node candidates, 5 frags, [REDACTED]

Micro B13: 4 lymph node candidates, 4 frags, [REDACTED]

Micro B14-B17: Pericolonic adipose tissue, 1 frag each, [REDACTED]

Part C, "proximal donut", consists of a circular tan/pink soft tissue fragment (1.1 x 1.6 cm in diameter) that is attached to metallic anvil and contains a

[page 3 of 3]
Pathology Report

black stitch. The specimen is entirely submitted for histological examination.

Micro C1: Proximal donut, 1 frag, .

Part D, "distal donut", consists of a tan/yellow soft tissue (1.5 x 1.2 x 0.5 cm) which is entirely submitted.

Micro D1: Distal donut, 1 frag, .

CASE NUMBER

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Final Diagnosis by Electronically signed on

Source: NCI Genomic Data Commons file 5b262346-471f-4eec-9602-55e40f4e1846 (TCGA-CK-6748.D8E78B5E-6E61-413A-B518-A8B77B986E86.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).